Somatic mutation profile of tumor specimen TCGA-B5-A0JT-01A (aliquot TCGA-B5-A0JT-01A-21D-A122-09) from TCGA case TCGA-B5-A0JT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 63.1 years (23,041 days).
Specimen TCGA-B5-A0JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84e12b21-6e7a-4f98-aeb4-f21df89e599c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JT-10A (Blood Derived Normal), aliquot TCGA-B5-A0JT-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2566ee18-d617-4198-a9b5-0f1ecb416989

The open-access MAF lists 67 somatic variants for this specimen: 56 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 46, Silent 11, Frame Shift Del 3, Splice Site 3, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 18/125 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 23/144 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- IQSEC2 | c.2983C>T p.R995W (on ENST00000642864 / NM_001111125.3; = p.R790W on NM_015075.2) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057521657, COSV64723299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 160/326 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 68/186 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13536G>T p.L4512F | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101291383; called by muse, mutect2
- ABL2 | c.3373G>T p.D1125Y (on ENST00000502732 / NM_007314.4; = p.D1110Y on NM_005158.5) | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61010965; called by muse, mutect2, varscan2
- ADGRB1 | c.1365C>A p.F455L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as COSV60091638; called by muse, mutect2, varscan2
- AKAP9 | c.8511del p.S2838Qfs*7 (on ENST00000359028; = p.S2814Qfs*7 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/137 reads (23%) | catalogued as COSV62356880; called by mutect2, pindel, varscan2
- ARID5B | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274987213, COSV54413935; called by muse, mutect2, varscan2
- BRMS1 | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); catalogued as rs762502004, COSV100240337, COSV60819648; called by mutect2, varscan2
- CALR3 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 92/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54168349; called by muse, mutect2, varscan2
- CHD2 | c.5287C>T p.R1763C | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1486760399, COSV67706629; called by muse, varscan2
- CNTN6 | c.2301C>A p.S767R | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV63161620; called by muse, mutect2, varscan2
- CYLC2 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs188765977, COSV66336036; called by muse, mutect2, varscan2
- DNAH3 | c.6217G>A p.V2073M | Missense Mutation (SNP) | VAF 70/581 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762157776, COSV54502748; called by muse, mutect2, varscan2
- FAT1 | c.11552T>C p.L3851S | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.08); catalogued as COSV71671875; called by muse, mutect2, varscan2
- GRHL2 | c.1485+1G>T p.X495_splice | Splice Site (SNP) | VAF 100/176 reads (57%) | catalogued as COSV52544307; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs747304979, COSV54559984; called by muse, mutect2, varscan2
- IGDCC3 | c.1171G>A p.G391S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.058); catalogued as rs201766054, COSV60076364; called by muse, mutect2, varscan2
- KMT2D | c.12823_12824insT p.Q4275Lfs*59 | Frame Shift Ins (INS) | VAF 29/100 reads (29%) | catalogued as COSV56409779; called by mutect2, pindel, varscan2
- KRT36 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs201247809, COSV60202450; called by muse, mutect2, varscan2
- KRT83 | c.1442C>T p.T481I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as rs1336528089, COSV53338290; called by muse, mutect2
- LRRC37B | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs1180301373, COSV58950887; called by muse, mutect2, varscan2
- MYH7 | c.4817G>A p.R1606H | Missense Mutation (SNP) | VAF 133/399 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs373514686, CM1310645; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- OPRL1 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs780562835, COSV61090915; called by muse, mutect2, varscan2
- OR14I1 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV100700505; called by muse, mutect2
- ORMDL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 84/158 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs200911531, COSV57876721; called by muse, mutect2, varscan2
- PCDHGA5 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.043); catalogued as COSV53896726; called by muse, mutect2, varscan2
- PCOLCE2 | c.363G>C p.K121N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV55997505; called by muse, mutect2, varscan2
- PRDM15 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs755429203, COSV54148719; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 101/254 reads (40%) | catalogued as rs146650273; called by pindel, varscan2
- PTPN23 | c.3009G>C p.Q1003H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55542558; called by muse, varscan2
- PTPN6 | c.1475G>A p.R492Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59683310; called by muse, mutect2, varscan2
- PTPRD | c.5578G>A p.V1860I | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100645618; called by muse, mutect2
- PTPRE | c.589-2A>G p.X197_splice | Splice Site (SNP) | VAF 20/240 reads (8%) | catalogued as COSV99618381; called by muse, mutect2
- PTPRT | c.1866-2A>G p.X622_splice | Splice Site (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100628759; called by muse, mutect2
- RAB3GAP2 | c.1652C>G p.A551G | Missense Mutation (SNP) | VAF 205/456 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62782119, COSV62782700; called by muse, mutect2, varscan2
- RADX | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1167035780, COSV100998873; called by muse, mutect2
- RHOXF2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.276); catalogued as rs1481913478, COSV65047632; called by muse, varscan2
- RYR2 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 74/439 reads (17%) | catalogued as COSV63660698; called by muse, mutect2, varscan2
- SPZ1 | c.1289G>T p.R430I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99698228; called by muse, mutect2
- STK39 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 39/480 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs762057185, COSV100596939; called by muse, mutect2
- TMED3 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV55302104; called by muse, mutect2, varscan2
- TMEM92 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as COSV100305205, COSV55946304; called by muse, mutect2
- TMX1 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs766355722, COSV63335527; called by muse, mutect2
- UBA5 | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV53893373; called by muse, mutect2, varscan2
- UBE2N | c.93C>A p.N31K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58866810; called by muse, mutect2, varscan2
- UBN1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 30/312 reads (10%) | catalogued as COSV99278273; called by muse, mutect2
- UGT2B10 | c.1384T>A p.W462R | Missense Mutation (SNP) | VAF 134/388 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55318521; called by muse, mutect2, varscan2
- UMODL1 | c.2874del p.L959Sfs*25 (on ENST00000408910 / NM_001004416.2; = p.L1087Sfs*25 on NM_173568.3) | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | catalogued as COSV68569250; called by mutect2, pindel, varscan2
- UNC5D | c.2347C>T p.R783W | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs776286236, COSV54768799; called by muse, mutect2, varscan2
- VAPA | c.425T>C p.M142T (on ENST00000400000 / NM_194434.3; = p.M187T on NM_003574.6) | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs773084616, COSV61297104; called by muse, mutect2, varscan2
- ZFAND2B | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs373368661; called by muse, mutect2, varscan2
- ZMIZ1 | c.2225G>T p.C742F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57889520; called by muse, mutect2, varscan2
- ZNF385D | c.4A>G p.R2G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV55745889; called by muse, mutect2, varscan2
- ADCY9 | c.2718C>T p.V906= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs373556046; called by mutect2, varscan2
- ARHGAP36 | c.1335G>A p.P445= | Silent (SNP) | VAF 55/160 reads (34%) | catalogued as rs768126902, COSV52263717; called by muse, mutect2, varscan2
- CACNA1F | c.3090G>A p.T1030= | Silent (SNP) | VAF 128/362 reads (35%) | catalogued as rs782287148, COSV59902948, COSV59903196; called by muse, varscan2
- DPEP1 | c.9C>T p.S3= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs548760657, COSV55358842; called by muse, mutect2, varscan2
- DUOX1 | c.2232G>A p.E744= | Silent (SNP) | VAF 19/173 reads (11%) | catalogued as rs780786500, COSV58477234; called by muse, mutect2, varscan2
- FTHL17 | c.138C>T p.D46= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as rs748349892, COSV63266258; called by muse, mutect2, varscan2
- NUCB1 | c.954C>T p.L318= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as rs771516747, COSV54385011; called by muse, mutect2, varscan2
- PARD3 | c.2118G>A p.A706= | Silent (SNP) | VAF 24/248 reads (10%) | catalogued as rs746450270, COSV100401439; called by muse, mutect2
- PCDHGA12 | c.1779G>A p.A593= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV52742957; called by muse, mutect2, varscan2
- TMEM107 | c.78C>T p.F26= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as rs991836698, COSV57100771; called by muse, mutect2, varscan2
- WDR26 | c.2139A>T p.T713= (on ENST00000414423 / NM_001379403.1; = p.T613= on NM_025160.7) | Silent (SNP) | VAF 103/238 reads (43%) | catalogued as COSV54353020; called by muse, mutect2, varscan2
